Gene-level copy-number profile of specimen HCM-BROD-0003-C71-85B from HCMI case HCM-BROD-0003-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 82.1 years (29,995 days).
Specimen HCM-BROD-0003-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 14.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7baccb6f-64e5-4bf9-8431-2fe7f105d100.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0003-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/9d6e3c76-248e-4d35-a490-99f0fa08d8c6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 79; copy number 2: 37; copy number 3: 15,248; copy number 4: 35,906; copy number 5: 7,106; copy number 6: 21; copy number 7: 5; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:79,915,252–79,926,725, 2 genes, copy number 9: LINC01979, LINC01978.

Autosomal genes at a single copy (total copy number 1): 79. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
